Surgical pathology report (de-identified scan), TCGA case TCGA-33-4587, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4587-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

1) LUNG, RIGHT MIDDLE LOBE (SEGMENTAL RESECTION): INFILTRATING
SMALL CELL UNDIFFERENTIATED CARCINOMA WITH FOCAL SQUAMOUS FEATURES
(3.2 CM). ANGIOLYMPHATIC INVASION IS IDENTIFIED. ALL SURGICAL
MARGINS ARE NEGATIVE FOR TUMOR ONE (1) LYMPH NODE AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR. SEE NOTE.

2) LYMPH NODES, STATION 7 (BX): ONE (1) LYMPH NODE AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

3) LYMPH NODES, L10 (BX): ONE (1) LYMPH NODE AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

NOTE: This case was shown at the daily quality assurance conference.

? for help, Cursor Keys to scroll, Q to Quit:

Or Choose: [G]rs_Des, [E]vnts, [I]nt_Prts, [C]ln_Hst, [B]il_Inf
[H]ist_Inf, [P]rnt_Rpt, [L]ab_Tsts, [A]Lab_LTR_Tsts, [J]HMCIS
[S]pec_List, [X]Tum_Bnk, [Z]Dth_Inf

Source: NCI Genomic Data Commons file b048ef85-f79c-4f76-bae6-3535031c0cae (TCGA-33-4587.6E5B11A3-0414-4AF4-8CD2-0E80C02B8BCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).